Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6945, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6945-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

- (A) RIGHT EXTENDED MODIFIED RADICAL NECK DISSECTION:
METASTATIC MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA INVOLVING
MATTED MASS OF SUBDIGASTRIC AND UPPER POSTERIOR CERVICAL
LYMPH NODES (5 X 3 X 1.5 CM) WITH EXTRACAPSULAR EXTENSION.
Thirty-nine cervical lymph nodes; no tumor present (0/4 submental;
0/7 subdigastric; 0/2 midjugular; 0/9 lower jugular; 0/10 upper
posterior cervical and 0/7 midposterior cervical).
- (B) LATERAL NASOPHARYNGEAL MARGIN:
Squamous and respiratory mucosa, no tumor present.
- (C) BUCCAL MUCOSA AND RETROMOLAR TRIGONE:
Squamous mucosa, no tumor present.
- (D) LINGUAL, TONGUE, FLOOR OF MOUTH MARGIN:
Squamous mucosa, no tumor present.
- (E) VALLECULA MARGIN:
Squamous mucosa, no tumor present.
- (F) BASE OF TONGUE:
Squamous mucosa, lymphoid tissue and salivary gland, no tumor present.
- (G) LEFT SOFT PALATE:
Squamous mucosa, no tumor present.
- (H) NASOPHARYNGEAL ROOF MARGIN:
Squamous mucosa, no tumor present.
- (I) RIGHT HARD PALATE MARGIN:
Squamous mucosa, no tumor present.
- (J) PARTIAL GLOSSECTOMY, PARTIAL MAXILLECTOMY, PARTIAL PHARYNGECTOMY, TOTAL
PALECTECTOMY - NASOPHARYNGECTOMY:
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA INVOLVING TONGUE,
RIGHT RETROMOLAR TRIGONE, HYPOPHARYNX, UVULA AND SOFT PALATE;
MAXIMUM DEPTH OF INVASION 1.4 CM, FOCAL PERINEURAL INVASION
PRESENT; DEEP MARGIN OF RESECTION FREE OF TUMOR. (SEE COMMENT)
- (K) TEETH:
Fifteen teeth (gross only).

COMMENT

The tumor measures 7.0 x 3.5 x 1.4 cm. The matted mass of
subdigastric and upper posterior cervical lymph nodes (5.0 x 3.0 x 0.5 cm)
shows 95% replacement by squamous carcinoma with focal extranodal extension
(3-4 mm).

SPECIMEN

- (A) RIGHT EXTENDED MODIFIED RADICAL NECK DISSECTION:
(B) LATERAL NASOPHARYNGEAL MARGIN:
(C) BUCCAL MUCOSA AND RETROMOLAR TRIGONE:
(D) LINGUAL, TONGUE, FLOOR OF MOUTH MARGIN:
(E) VALLECULA MARGIN:
(F) BASE OF TONGUE:
(G) LEFT SOFT PALATE:
(H) NASOPHARYNGEAL ROOF MARGIN:

[page 2 of 2]
-
- (I) RIGHT HARD PALATE MARGIN:
- (J) PARTIAL GLOSSECTOMY, PARTIAL MAXILLECTOMY, PARTIAL PHARYNGECTOMY, TOTAL
- (K) TEETH:
-
-

Source: NCI Genomic Data Commons file 938b7da8-b058-42c6-8043-757675191ac5 (TCGA-CV-6945.D39DCB26-8580-4762-9ABC-2C2F5CF70D88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).